Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A269, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A269-01A (Primary Tumor).

[page 1 of 2]
100-0-3

Melanoma, superficial spreading 8743/3

Site: skin, back C44.5 per 4/27/11

SPECIMENS:

- A. SENTINEL LYMPH NODE RIGHT AXILLA
- B. SENTINEL LYMPH NODE #1 LEFT AXILLA
- C. LYMPHATIC TISSUE
- D. MELANOMA FROM BACK

DIAGNOSIS:

- A. SENTINEL LYMPH NODE RIGHT AXILLA:
- MICROMETASTATIC MALIGNANT MELANOMA IN ONE OF ONE SENTINEL LYMPH NODES(1/1).
- B. SENTINEL LYMPH NODE #1 LEFT AXILLA:
- REACTIVE HYPERPLASIA WITH DIFFUSE MELANOSIS, NO TUMOR SEEN IN ONE LYMPH NODE (0/1).
- C. LYMPHATIC TISSUE:
- FIBROADIPOSE TISSUE, NO LYMPHOID TISSUE OR TUMOR IDENTIFIED.
- D. MELANOMA FROM BACK, EXCISION:
- MALIGNANT MELANOMA, SUPERFICIAL SPREADING TYPE WITH DOMINANT ULCERATED VERTICAL GROWTH PHASE NODULE, CLARK'S LEVEL V, AT LEAST 5 CM. IN THICKNESS WITH SATELLITOSIS(X2).
- SEE TEMPLATE.

MELANOMA TEMPLATE

Specimen Type:	Excision; Sentinel Lymph Node Biopsy
Histologic Type:	Superficial spreading type with dominant vertical growth phase nodule ✓
Clark's level:	V
Thickness (Breslow):	5.0 cm
Host reaction(TILS):	Non Brisk
Mitotic rate (#/mm2):	1.60/mm2
Vertical growth:	Prominent (with necrosis)
Vasc/lymphatic invasion:	Present
Ulceration:	Present
Regression:	Absent
Precursor:	Absent
Satellites:	2 lesions (inf lat margin - slide D4 and adjacent to deep margin D21).
Surgical margins:	Involved- inferior lateral (D4) by satellite lesion
Lymph nodes:	Positive (1/2)
Extracapsular extension:	No
IHC results (sentinel lymph node):	S-100 and HMB-45 positive
Pathologic Stage:	pT4b N3 Mx

SPECIMEN(S):

- A. SENTINEL LYMPH NODE RIGHT AXILLA B. SENTINEL LYMPH NODE #1 LEFT AXILLA C. LYMPHATIC TISSUE D. MELANOMA FROM BACK

CLINICAL HISTORY:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

TPA - Lymph node. sentinel right axilla, biopsy: Pigmented macrophages. No melanoma seen by Dr.. Called to D
TPB - Lymph node, sentinel, biopsy: No melanoma seen by Dr.. Called to Dr

GROSS DESCRIPTION:

- A. SENTINEL LYMPH NODE RIGHT AXILLA:

[page 2 of 2]
Received fresh for frozen section in a container labeled with the patient's name is a brown to black lymph node measuring 1.8 x 1.5 x 0.7 cm. The node is bisected and entirely submitted in two cassettes.

B. SENTINEL LYMPH NODE #1 LEFT AXILLA

Received fresh in a container labeled with the patient's name is one brown to black lymph node measuring 2.0 x 1.5 x 1 cm. The node is sectioned and submitted in three cassettes.

C. LYMPHATIC TISSUE:

Received in formalin is a pink-tan adipose tissue measuring 0.5 x 0.5 x 0.2 cm. The specimen is bisected.

Summary of sections:

C1: tissue entirely submitted

D. MELANOMA FROM BACK:

Received in formalin is a resection of skin of the back. The specimen is round to oval in shape measuring 16.0 x 15.0 x 6.0 cm. There is an irregular shaped, raised, centrally located brown fungating mass measuring 11.0 x 10.0 x 2.0 (depth). This lesion is approximately 1 cm. from the superior margin, 3 cm. from the right lateral margin, 2.5 cm. from the inferior margin and 3 cm. from the medial margin. A small suture indicates the superior margin while a long suture indicates the right lateral margin. Margins are shaved at the superior, superior-lateral, lateral, inferior-lateral, inferior, inferior-medial, medial and superior-medial areas. The deep margin is inked black and the specimen is serially sectioned. The maximum depth of the tumor is about 5 cm. A small separate brown lesion measuring 1.5 x 0.5 cm. is seen beneath normal appearing skin and is approximately 1.5 cm. away from the main lesion and appears to be 0.5 cm. from the deep margin.

Summary of sections:

D1-D8: superior margin

D2: superior-lateral margin

D3: lateral margin

D4: inferior-lateral margin

D5: inferior margin

D6: inferior-medial margin

D7: medial margin

D8: superior-medial margin

D9-D15: mass plus deep margin

D16-D20: mass

D21: second lesion

Gross Dictation: ()
Microscopic/Diagnostic Dictation: PATHOLOGIST
Final Review: Pathologist,
Final: Pathologist,

Criterion	Yes	No
Tumor, Tumor Site Discrepancy		
IMPA Discrepancy		
First Malignancy History		
Real/Syn. Chronology Primary Noted		

Source: NCI Genomic Data Commons file 1a6d4396-3beb-49ca-9cf4-452962d33859 (TCGA-GN-A269.AFB70554-E2A6-4CB5-9C16-0B5B82F03537.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).